Somatic mutation profile of tumor specimen TCGA-WB-A815-01A (aliquot TCGA-WB-A815-01A-11D-A35I-08) from TCGA case TCGA-WB-A815, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 68.1 years (24,859 days).
Specimen TCGA-WB-A815-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a196c297-e905-4e34-8d39-92c78d141928.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A815-10A (Blood Derived Normal), aliquot TCGA-WB-A815-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ed78244-3871-45e2-bdd5-60c063aa70bc

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLI3 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.154); catalogued as rs186337909; ClinVar: likely benign; called by muse, mutect2, varscan2
- PIK3R5 | c.1931C>T p.A644V | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs1364926476, COSV52650131; called by muse, mutect2, varscan2
- RAD51AP1 | c.850G>C p.D284H (on ENST00000228843 / NM_001130862.2; = p.D267H on NM_006479.5) | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV99961382; called by muse, mutect2, varscan2
- TINAG | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99449822; called by muse, mutect2
- ACOT12 | c.780A>C p.E260D | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CNST | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GPNMB | c.492C>G p.H164Q | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- HECTD4 | c.7268A>C p.Y2423S | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSDL2 | c.703C>G p.P235A | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- LOXL4 | c.1522del p.Q508Rfs*29 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- PIGP | c.16A>C p.T6P | Missense Mutation (SNP) | VAF 59/101 reads (58%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RRAS2 | c.180A>T p.R60S | Missense Mutation (SNP) | VAF 79/119 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- UPF2 | c.883A>G p.I295V | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- UTRN | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- CD101 | c.2337T>C p.A779= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as rs1553187085; called by muse, mutect2, varscan2
- CEP192 | c.2604A>G p.T868= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs1056687942; called by muse, mutect2, varscan2
- DYM | c.699C>A p.A233= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- OGDHL | c.2019G>C p.R673= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as rs1323293590; called by muse, mutect2
